Gene-level copy-number profile of tumor specimen HCM-SANG-0537-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0537-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0537-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2534e901-22f3-41be-841b-465e36444a04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0537-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/09fe042b-ea73-4f39-b38b-da414df96eb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 10,309; copy number 2: 42,846; copy number 3: 4,636; copy number 4: 433; copy number 5: 157.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,841,357, 4 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–1): DEFB108A.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 157 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,511,951–169,630,193, 2 genes, copy number 5: F5, SELP.
- chr20:31,257,664–31,801,805, 31 genes, copy number 5: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:62,307,955–64,327,972, 124 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
